Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YR, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YR-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

ICD-O-3
Fibromyxosarcoma 8811/3
Site @ Chest wall NOS
C49.3
Jt 8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with a chest wall mass.

Specimens Submitted:

1: Radical resection of right chest wall mass

DIAGNOSIS:

1. Soft tissue, right chest wall, mass; radical resection:
- Myxofibrosarcoma, high grade.
- Tumor measures 6 cm in greatest dimension.
- Tumor involves deep soft tissue and skeletal muscle.
- Mitoses 12 / 10 high power fields.
- Surgical resection margins are free of tumor.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) . The specimen is received fresh, labeled " radical resection of right chest wall mass , Short stitch superior margin, long stitchlateral. " and it consists of a oriented tissue associated with skin ellipse (11.5 x2 cm) and skeletal muscle measuring 13 cm from medial to lateral, 9.5 cm from superficial to deep, 6 cm from superior to inferior. Ink is placed as: deepblack, superiorblue, inferiorgreen, medial ---red, lateral yellow. Sectioning along deep to superficial axis reveals a 6 x 5.8 x 5.4 cm well defined intra-muscular mass. It is 3 cm from the skin, 0.5 cm from the deep, 0.4 cm from the lateral, 2 cm from the medial 1.5 cm from the superior, 1.5 cm from inferior. The cut surface is white and homogenous, gelatinous appearance is appreciated. A small portion of the mass is submitted for TPS, gross photos were taken. Representative sections are submitted.

Summary of sections:

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2

SXMtumor and superior margin
IXMtumor and inferior margin
MXMtumor and medial margin
LXMtumor and lateral margin
DXMtumor and deep margin
T--tumor
SKskin

Summary of Sections:
Part 1: Radical resection of right chest wall mass

Block	Sect. Site	PCs
2	DXM	3
2	IXM	3
2	LXM	3
2	MXM	3
2	SK	3
2	SXM	3
6	T	7

** End of Report **

iw 7/23/13

Criteria	No
1. gross discrepancy	✓
2. gross Tumor Site discrepancy	✓
3. gross Discrepancy	✓
4. gross Discrepancy History	✓
5. gross Discrepancy History	✓
6. gross Discrepancy History	✓
7. gross Discrepancy History	✓
8. gross Discrepancy History	✓
9. gross Discrepancy History	✓
10. gross Discrepancy History	✓

Signature: [Signature]

Source: NCI Genomic Data Commons file 034667d5-503d-49f7-81f5-0fffe269ddea (TCGA-DX-A6YR.1F59D39D-6F6A-4962-91E3-DA592B27CFCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).